Surgical pathology report (de-identified scan), TCGA case TCGA-B2-5639, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site Christiana Healthcare, specimen TCGA-B2-5639-01A (Primary Tumor).

[page 1 of 2]
SPECIMEN

Left kidney

CLINICAL NOTES

PRE-OP DIAGNOSIS: Renal cancer.

GROSS DESCRIPTION

Received fresh, labeled "left kidney" is a 361 gram, 12.5 x 6.0 x 6.0 cm. left kidney with a moderate amount of attached mesonephric adipose tissue and propatent 5.5 cm. ureter averaging 0.4 cm. in diameter. Red brown tumor appears to be present within one of the vascular structures at the hilum. An irregular, 1.6 cm. in greatest dimension fragment of yellow orange adrenal parenchyma is identified along the surface of the specimen. The renal capsule is delicate tan pink and strips with relative ease from the underlying cortical surface. The renal pelvis is smooth tan white. There is a poorly circumscribed, 6.5 x 6.0 x 5.0 cm. tan red to yellow orange tumor mass occupying the superior pole and extending into the mid region of the kidney. The tumor appears to extend to within 0.1 cm. of the inked surface of the specimen (see blocks 2 through 4). The parenchyma throughout the remainder of the specimen is uniform red brown with a moderately well defined cortical medullary junction and a maximal cortical thickness of 1.1 cm. The renal pelvis is smooth tan white. No additional abnormalities are noted. A portion of tumor and a portion of normal are submitted for tissue procurement as requested. Representative sections are submitted in ten blocks as labeled. RS-10.

BLOCK SUMMARY: 1 - Vascular and ureteral margins; 2-4 - tumor to inked surface of specimen; 5,6, 7 - tumor to renal pelvis and fat; 8 uadrisected adrenal parenchyma; 9,10 - random normal kidney.

[page 2 of 2]
MICROSCOPIC DESCRIPTION

Histologic type: Clear cell carcinoma.
Histologic grade (Fuhrman Nuclear Grade): Fuhrman nuclear grade 3.
Primary tumor (pT): Extends into the renal vein and also involves the fat
of the renal sinus (pT3).
Margins of resection: Positive; clear cell carcinoma is present within the
lumen of the renal vein at the margin.
Regional lymph nodes (pN): None submitted (pNX).
Distant metastasis (pM): Cannot be evaluated by this specimen (pMX).
Adrenal gland: Uninvolved.
Vascular invasion: Present.
Non-neoplastic kidney: Unremarkable.
Other findings: None.

4

DIAGNOSIS

Left kidney, nephrectomy:
- Renal cell carcinoma, clear cell type, 6.5 cm, present in the lumen of the renal vein at the surgical margin.
Adrenal, left , resection:
- No evidence of malignancy.

--- End Of Report ---

Source: NCI Genomic Data Commons file 8c7f5c65-dee2-4168-9b92-3316681ac978 (TCGA-B2-5639.CCA79CCC-88F2-4673-B474-6F3B549A7AF1.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).